Somatic mutation profile of tumor specimen TCGA-2J-AABE-01A (aliquot TCGA-2J-AABE-01A-12D-A40W-08) from TCGA case TCGA-2J-AABE, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Body of pancreas; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 73.8 years (26,943 days).
Specimen TCGA-2J-AABE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e03278c1-489b-4c4d-bac1-239fd42e2528.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2J-AABE-10A (Blood Derived Normal), aliquot TCGA-2J-AABE-10A-01D-A40W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a0a481b5-9bca-446a-81fc-0c0c52191635

The open-access MAF lists 40 somatic variants for this specimen: 29 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 10, Splice Site 2, In Frame Del 1, Nonsense Mutation 1, Frame Shift Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 32/215 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC6 | c.3985C>G p.P1329A | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.634); catalogued as COSV99227940; called by muse, mutect2
- ADAMTS16 | c.2797G>A p.V933M | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.969); catalogued as rs995733642, COSV56997641; called by muse, mutect2
- AKT3 | c.569T>C p.V190A | Missense Mutation (SNP) | VAF 12/314 reads (4%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.697); catalogued as COSV99793941; called by muse, mutect2
- CISH | c.415C>G p.R139G (on ENST00000348721 / NM_145071.4; = p.R156G on NM_013324.6) | Missense Mutation (SNP) | VAF 40/226 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.963); catalogued as COSV100811702; called by muse, mutect2, varscan2
- CRACD | c.2497C>T p.P833S | Missense Mutation (SNP) | VAF 55/298 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.083); catalogued as COSV99948412; called by muse, mutect2, varscan2
- HLCS | c.1369C>T p.R457C | Missense Mutation (SNP) | VAF 67/374 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as rs547391411, COSV60791180; called by muse, mutect2, varscan2
- KCNA5 | c.835C>A p.R279S | Missense Mutation (SNP) | VAF 62/406 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as COSV52906686, COSV52907442; called by muse, mutect2, varscan2
- LCT | c.2468G>A p.S823N | Missense Mutation (SNP) | VAF 26/722 reads (4%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV99928392; called by muse, mutect2
- LRFN1 | c.620T>A p.V207E | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); catalogued as COSV99952571; called by muse, mutect2, varscan2
- MARCHF8 | c.487G>A p.V163I | Missense Mutation (SNP) | VAF 119/450 reads (26%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs573798318, COSV60570420; called by muse, mutect2, varscan2
- MED18 | c.271C>T p.P91S | Missense Mutation (SNP) | VAF 126/658 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV100868903; called by muse, mutect2, varscan2
- NEK4 | c.1882A>G p.M628V | Missense Mutation (SNP) | VAF 194/995 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV99237077; called by muse, mutect2, varscan2
- NLRP8 | c.2359C>T p.R787W | Missense Mutation (SNP) | VAF 53/332 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.023); catalogued as rs183661608, COSV52585764; called by muse, mutect2, varscan2
- PHIP | c.4565C>T p.S1522F | Missense Mutation (SNP) | VAF 60/273 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV99243245; called by muse, mutect2, varscan2
- PHYKPL | c.502G>C p.A168P | Missense Mutation (SNP) | VAF 43/228 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100069433; called by muse, mutect2, varscan2
- PKHD1 | c.1693+1G>A p.X565_splice | Splice Site (SNP) | VAF 76/478 reads (16%) | catalogued as COSV100580816; called by muse, mutect2, varscan2
- PLS1 | c.498-2A>T p.X166_splice | Splice Site (SNP) | VAF 42/250 reads (17%) | catalogued as COSV100537919; called by muse, mutect2, varscan2
- RARS2 | c.16C>T p.R6C | Missense Mutation (SNP) | VAF 35/172 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs201899366, COSV57638114, COSV57641021; called by muse, mutect2, varscan2
- RIMS2 | c.3938C>T p.S1313F | Missense Mutation (SNP) | VAF 39/238 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV104385565, COSV99155694; called by muse, mutect2, varscan2
- RNF43 | c.64C>T p.Q22* | Nonsense Mutation (SNP) | VAF 51/230 reads (22%) | catalogued as COSV60415481; called by muse, mutect2, varscan2
- SCAF1 | c.986C>T p.P329L | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as rs754690731, COSV100862027; called by muse, varscan2
- SMAD4 | c.1025del p.P342Lfs*42 | Frame Shift Del (DEL) | VAF 91/437 reads (21%) | catalogued as COSV61692357, COSV61697029; called by mutect2, pindel, varscan2
- SNX6 | c.502A>G p.I168V (on ENST00000652385; = p.I40V on NM_021249.5) | Missense Mutation (SNP) | VAF 43/273 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs530960694, COSV100751345; called by muse, mutect2, varscan2
- SPINK2 | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 34/184 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV99954134; called by muse, mutect2, varscan2
- ZNF582 | c.80A>C p.Q27P | Missense Mutation (SNP) | VAF 87/524 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100018454; called by muse, mutect2, varscan2
- ZNF585B | c.1326C>A p.H442Q | Missense Mutation (SNP) | VAF 113/707 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.085); catalogued as COSV100459262, COSV100459407; called by muse, mutect2, varscan2
- CENPF | c.9076A>T p.S3026C | Missense Mutation (SNP) | VAF 16/549 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.205); called by muse, mutect2
- H1-5 | c.234_236del p.K78del | In Frame Del (DEL) | VAF 155/940 reads (16%) | called by pindel, varscan2
- CD1D | c.78C>T p.F26= | Silent (SNP) | VAF 331/2016 reads (16%) | catalogued as rs762862302, COSV100939525; called by mutect2, varscan2
- DNAH1 | c.3486G>A p.L1162= | Silent (SNP) | VAF 28/165 reads (17%) | catalogued as COSV101324426; called by muse, mutect2
- DYNC1I1 | c.345C>T p.G115= | Silent (SNP) | VAF 55/292 reads (19%) | catalogued as rs145885345; called by muse, mutect2, varscan2
- GNL3 | c.1581A>G p.T527= | Silent (SNP) | VAF 49/304 reads (16%) | catalogued as COSV99803474; called by muse, mutect2, varscan2
- PRX | c.2907T>C p.A969= | Silent (SNP) | VAF 24/518 reads (5%) | catalogued as COSV99397360; called by muse, mutect2
- SEMA4C | c.1722G>A p.V574= | Silent (SNP) | VAF 30/232 reads (13%) | catalogued as COSV100560693; called by muse, mutect2, varscan2
- TBC1D19 | c.1578C>G p.T526= | Silent (SNP) | VAF 53/357 reads (15%) | catalogued as COSV99335824; called by muse, mutect2, varscan2
- UTRN | c.2652C>T p.G884= | Silent (SNP) | VAF 16/270 reads (6%) | catalogued as COSV100839426; called by muse, mutect2
- ZNF823 | c.795A>G p.R265= (on ENST00000341191 / NM_001297610.2; = p.R221= on NM_017507.2) | Silent (SNP) | VAF 48/320 reads (15%) | catalogued as COSV100362399; called by muse, mutect2, varscan2
- ZSCAN25 | c.393A>T p.P131= | Silent (SNP) | VAF 41/474 reads (9%) | catalogued as rs1482165734, COSV99500371; called by muse, mutect2
- ZNFX1 | chr20:49280351 C>T | 5'Flank (SNP) | VAF 27/267 reads (10%) | catalogued as rs778707314; called by muse, mutect2, varscan2
